Surgical pathology report (de-identified scan), TCGA case TCGA-GR-A4D4, project TCGA-DLBC (Lymphoid Neoplasm Diffuse Large B-cell Lymphoma), tissue source site University of Nebraska Medical Center (UNMC), specimen TCGA-GR-A4D4-01A (Primary Tumor).

[page 1 of 5]
Department of Pathology and Microbiology

Name: [REDACTED]
Hosp No: [REDACTED]
DOB: [REDACTED]
Sex: F Age: [REDACTED]
Loc: [REDACTED] Room: [REDACTED]
Accession No: [REDACTED]
Date Taken: [REDACTED]
Date Received: [REDACTED]
Submitted by: [REDACTED]
Client: [REDACTED]

Surgical Pathology

Final Diagnosis:

LEFT ILEAL MASS, EXCISION: SOFT TISSUE WITH DIFFUSE LARGE B-CELL LYMPHOMA, ANAPLASTIC TYPE (SEE COMMENT). (B-DLCL-AP)

Diagnosis Comment:

The lymphoma cells are large and pleomorphic cells, and the tumor shows a high mitotic rate and large areas of necrosis. Immunostains show a B-cell phenotype, and an ALK stain is negative.

KDO3

lymphoma, diffuse,
large B-cell, NOS

968013 Signed:

Site: Soft tissue, NOS C49.9

Path: ileum C17.2 9-20-12 RD

History:

The patient is a [REDACTED]-year-old female with a history of left hemipelvis lesion.

Intraoperative Diagnosis:

Soft tissue, left ileum mass, excision (FSA1): Malignant non-small cell neoplasm. Final classification deferred to permanents. This was performed by [REDACTED] and reported in person by [REDACTED] to Dr. [REDACTED]

Source/Gross:

The specimen is received fresh in a single container labeled "[REDACTED]" and is designated "left ileal mass" and consists of four fragments of tan-gray soft tissue measuring from 0.6 to 2.2 cm in greatest dimension. There is also a fragment of unremarkable adipose tissue which measures 1.9 x 0.6 x 0.6 cm.

These materials were examined by all those listed to establish the diagnosis.

Responsible staff pathologist

[page 2 of 5]
Name: [REDACTED] D.O.B. [REDACTED] Sex: F Accession No: [REDACTED]
Submitted by: [REDACTED] Date Taken: [REDACTED] Hosp No: [REDACTED]

Surgical Pathology

Representative sections of the fragments are submitted for frozen section diagnosis in cryoblock FSA1.
This cryoblock is then submitted for immunohistochemical studies (see below).

The specimen is submitted as per the Lymphoma Study Group Protocol:

Touch preps are made -Two.

Fixed in formalin for 24 hours -Please see code of sections below.

Frozen in OCT for immunohistochemical studies -Four pieces ranging in maximum dimension from 0.7 to 1.4 cm.

Placed sterilely in medium for cytogenetics -

Frozen in foil for molecular diagnostic studies -One piece (2.0 x 0.9 x 0.1 cm).

Fixed in B-plus -One piece (2.0 x 1.1 x 0.2 cm), cassette A2.

The remainder of the specimen is submitted as per code of sections [REDACTED]

Code of Sections:

A3-A4 remainder of lesion
A5 unremarkable adipose tissue

Microscopic:

IMMUNOPEROXIDASE REPORT

PARAFFIN TISSUE - [REDACTED]

B-Cell Markers		T-Cell Markers		Other Markers	
CD20(L26)	+* ✓	CD45RO(UCHL1)	ND	CD45(LCA)	+* ✓
CD79a	ND	CD43(L60)	ND	CD30(Ber-H2)	- ✓
CD10	+ ✓	CD3	-* ✓	CD15(Leu M1)	ND
PAX5	+ ✓	CD5	- ✓	BCL-2	+ ✓
				BCL-6	+ ✓
				ALK	- ✓
				EBERs	- ✓
				RNA Control	+ ✓
				S100	-* ✓
				Pankeratin	-* ✓
				MUM1	- ✓

[page 3 of 5]
Name: [REDACTED] D.O.B. [REDACTED] Sex: F Accession No: [REDACTED]
Submitted by: [REDACTED] Date Taken: [REDACTED] Hosp No: [REDACTED]

Surgical Pathology

* = CD3 and CD20 also performed on block A3. CD45, S100, and Pankeratin performed on block A3.

INTERPRETATION: The paraffin markers indicate a B-cell phenotype, the lymphoma cells have a germinal center B-cell phenotype.

The study was developed and its performance characteristics determined by [REDACTED] Immunoperoxidase Laboratory. It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments (CLIA) as qualified to perform high complexity clinical laboratory testing.

[REDACTED]

[REDACTED]

[page 4 of 5]
SURGICAL PATHOLOGY
SPECIMEN REQUEST FORM

PATIENT INFORMATION

NAME: _____

MEDICAL REC _____

DATE OF BIRTH: _____

SEX: ☐ Male☐ Female

NO

CLINICAL HISTORY, PRE OPERATIVE DIAGNOSIS, POST OPERATIVE DIAGNOSIS, OR OTHER PERTINENT LABORATORY TESTS:

Left Hemipelvis lesion

POSSIBLE DUPLICATE
PATIENTSPECIAL REQUEST: _____
(Please specify)

ORDERING PROVIDER: _____

REFERRING PHYSICIAN: _____

DATE/TIME SPECIMEN COLLECTION _____

SPECIMEN SOURCE: _____

- Left Breast Mass
- _____
- _____
- _____
- _____
- _____
- _____
- _____
- _____

FROZEN SECTION: _____

YES ☒NO ☐

R NO. _____

EXT. _____

FROZEN SECTION DIAGNOSIS: _____

Malignant non-small cell carcinoma.
Final classification deferred to permanent.

PATHOLOGIST SIGNATURE: _____

REPORT TO: _____

TIME RECEIVED: _____

TIME REPORTED: _____

CREW CHECKLIST

- ☒ Patient's ID Check
- ☒ Site Verification
- ☒ Label Verification
- ☒ Form Complete
- ☒ Specimen and Box _____

LAB USE ONLY

[page 5 of 5]
IMMUNOPEROXIDASE REPORT

Patient: [REDACTED]

Surgical #: [REDACTED]

LR# [REDACTED]

Outside Surgical #: [REDACTED]

Date: [REDACTED]

☐ Referral Immunostains Reviewed AND / OR ☒ Done at [REDACTED]

PARAFFIN TISSUE - Outside Surgical # [REDACTED]

B-Cell Markers

T-Cell Markers

Other Markers

CD20(L26) + *

CD79a -

Kappa (ISH) -

Lambda (ISH) -

CD22 -

CD10 +

PAK5 +

-

-

-

CD45RO(UCHL1) -

CD43(L60) -

CD3 - *

CD5 -

CD2 -

CD4 -

CD7 -

CD8 -

-

-

-

CD45(LCA) +

CD30(Ber-H2) -

CD15(Leu M1) -

BCL-2 +

BCL-6 +

Cyclin D1 -

ALK -

BMA -

Ki-67 -

CD21 -

EBERs -

MMR 4-5/0 -

S100 -

PanCKIT -

PANM1 -

-

-

-

* Also performed on block A3

I = Indeterminate

If in situ hybridization, please check as appropriate:

ASR: ☐ Kappa/Lambda ☒ EBV ☐ Kappa/Lambda and EBV

Quick Test: ASREL ASREBV ASRLABV

INTERPRETATION (Circle):

1. Monoclonal B-cell lymphoma (IgG, IgA, IgM, IgD, kappa, lambda).
2. B-cell lymphoma, surface Ig negative.
3. Consistent with peripheral T-cell lymphoma, (helper/inducer, cytotoxic/suppressor) cell type.
4. Consistent with Hodgkin's disease, (classical type, lymphocyte-predominant type).
5. The paraffin markers indicate a (B-cell, T-cell, null) phenotype.
6. Specify: the lymphoma cells have a GCB phenotype

PATHOLOGIST: [REDACTED]

Source: NCI Genomic Data Commons file fd065690-70a9-4514-8f7f-ea5d4f4a626b (TCGA-GR-A4D4.5545A881-6000-458C-B133-39AA45CA10EE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).